Somatic mutation profile of cancer-model specimen HCM-WCMC-1281-C67-85A (3D Organoid; aliquot HCM-WCMC-1281-C67-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-1281-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 36.1 years (13,184 days).
Specimen HCM-WCMC-1281-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cef31c6c-4c39-42d7-a7f6-833017d2c48b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1281-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-1281-C67-10A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/623828fb-2367-4611-bfec-4b9485d9b906

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 21, Nonsense Mutation 7, Splice Region 2, 3'UTR 2, Frame Shift Del 2, Splice Site 2, Translation Start Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 360/361 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKS3 | c.573+1G>A p.X191_splice | Splice Site (SNP) | VAF 217/217 reads (100%) | catalogued as rs942646086, COSV58508849; called by muse, mutect2, varscan2
- ARAP2 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs768743432; called by muse, mutect2, varscan2
- C6orf62 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 266/411 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1193896578; called by muse, mutect2, varscan2
- CEP63 | c.2023C>T p.H675Y | Missense Mutation (SNP) | VAF 186/564 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1308001602; called by muse, mutect2, varscan2
- CNIH4 | c.69C>T p.F23= | Splice Region (SNP) | VAF 156/578 reads (27%) | catalogued as COSV100837027, COSV100837072; called by muse, mutect2, varscan2
- CYP2C9 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1042378453; called by muse, mutect2
- EFHC2 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101375478; called by muse, mutect2, varscan2
- ELAPOR2 | c.524G>A p.R175H (on ENST00000450689 / NM_001142749.3; = p.R8H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/421 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs778084845, COSV51887354; called by muse, mutect2, varscan2
- GIPR | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 190/878 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as COSV99624313; called by muse, mutect2, varscan2
- ITGA10 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 236/640 reads (37%) | catalogued as rs781934718, COSV100995029; called by muse, mutect2, varscan2
- LAMA5 | c.1940G>C p.G647A | Missense Mutation (SNP) | VAF 185/1012 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV53365504; called by muse, mutect2, varscan2
- LHFPL3 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 107/397 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as rs1157027115; called by muse, varscan2
- MAML1 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 511/1098 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs888518311, COSV52985126; called by muse, mutect2, varscan2
- MBOAT2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs955335450, COSV60012040; called by muse, mutect2, varscan2
- MCF2 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs1225634875; called by muse, mutect2, varscan2
- MGAT5B | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 223/436 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs770096837; called by muse, mutect2, varscan2
- MX2 | c.870C>T p.I290= | Splice Region (SNP) | VAF 224/356 reads (63%) | catalogued as rs1219707900; called by muse, mutect2, varscan2
- MYH15 | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 139/379 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as rs372918633, COSV99843004; called by muse, mutect2, varscan2
- NCKAP1L | c.364-1G>A p.X122_splice | Splice Site (SNP) | VAF 174/174 reads (100%) | catalogued as COSV53203466, COSV99515024; called by muse, mutect2, varscan2
- OR11H4 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 207/433 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV59560808; called by muse, mutect2, varscan2
- PKDREJ | c.2698A>T p.N900Y | Missense Mutation (SNP) | VAF 235/449 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99478593; called by muse, mutect2, varscan2
- PRMT1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 270/554 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV67159129, COSV67159911; called by muse, mutect2, varscan2
- RP1 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 235/789 reads (30%) | catalogued as COSV55124112; called by muse, mutect2, varscan2
- RUNX1 | c.416G>C p.R139P (on ENST00000344691 / NM_001001890.3; = p.R166P on NM_001754.5) | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM992139, COSV55866502, COSV55867644, COSV55875824; called by muse, mutect2, varscan2
- SAMD9 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 15/521 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV66073774; called by muse, mutect2
- SHB | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 606/614 reads (99%) | catalogued as COSV66621088; called by muse, mutect2, varscan2
- TAS2R42 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 211/438 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.328); catalogued as rs1049765499; called by muse, mutect2, varscan2
- TDRD5 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779980049; called by muse, mutect2, varscan2
- TMEM271 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 75/154 reads (49%) | PolyPhen possibly damaging (0.833); catalogued as rs1305631982; called by muse, mutect2, varscan2
- WDFY4 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs762595518; called by muse, mutect2
- ZNF580 | c.415C>G p.R139G | Missense Mutation (SNP) | VAF 560/1194 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs1397268412, COSV54401240; called by muse, mutect2, varscan2
- ZNF646 | c.5051G>A p.R1684H | Missense Mutation (SNP) | VAF 285/581 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747720125; called by muse, mutect2, varscan2
- ZNF782 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 206/395 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100001703; called by muse, mutect2, varscan2
- ALDH1A2 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- APP | c.2027G>C p.R676P | Missense Mutation (SNP) | VAF 135/729 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BBX | c.2088dup p.F697Ifs*8 | Frame Shift Ins (INS) | VAF 88/324 reads (27%) | called by mutect2, varscan2
- CA2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 281/562 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC62 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 179/368 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC88A | c.5429C>T p.S1810L (on ENST00000436346 / NM_001365480.1; = p.S1782L on NM_018084.5) | Missense Mutation (SNP) | VAF 427/428 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP112 | c.1052_1056del p.L351Qfs*2 | Frame Shift Del (DEL) | VAF 88/192 reads (46%) | called by mutect2, pindel, varscan2
- CEP295 | c.6661_6665del p.N2221Efs*21 | Frame Shift Del (DEL) | VAF 97/221 reads (44%) | called by mutect2, pindel, varscan2
- CHD6 | c.1571G>A p.W524* | Nonsense Mutation (SNP) | VAF 324/680 reads (48%) | called by muse, mutect2, varscan2
- CILP2 | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 62/696 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- COL12A1 | c.2884A>T p.I962L | Missense Mutation (SNP) | VAF 175/568 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIPK1A | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GBA | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 287/516 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GSTA1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 309/478 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- IHO1 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHDC8A | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 842/1084 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KMT2B | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 242/970 reads (25%) | called by muse, mutect2, varscan2
- LAMA5 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 137/613 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- LPP | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 109/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LRRC7 | c.4241A>G p.H1414R (on ENST00000651989 / NM_001370785.2; = p.H1334R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MBD6 | c.404T>C p.F135S | Missense Mutation (SNP) | VAF 383/384 reads (100%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MFSD9 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 256/256 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR52R1 | c.675G>C p.L225F | Missense Mutation (SNP) | VAF 403/404 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OSBPL1A | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PI4K2B | c.669C>G p.D223E | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PIKFYVE | c.3340C>T p.Q1114* | Nonsense Mutation (SNP) | VAF 191/368 reads (52%) | called by muse, mutect2, varscan2
- PTBP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 187/355 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RASGRF1 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 133/433 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- REEP3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 250/251 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL1 | c.3775G>A p.G1259S | Missense Mutation (SNP) | VAF 644/644 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3D21 | c.372G>C p.K124N (on ENST00000453908 / NM_001162530.2; = p.K13N on NM_024676.5) | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SLTM | c.3041C>G p.S1014C | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TAF1D | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TCF7 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 152/207 reads (73%) | SIFT tolerated (0.76); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TRAF6 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 175/344 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- TREM1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 210/615 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- UBR4 | c.13369G>C p.E4457Q | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP7 | c.2779A>G p.K927E | Missense Mutation (SNP) | VAF 169/399 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WASF2 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZFHX3 | c.6643_6645del p.P2215del | In Frame Del (DEL) | VAF 356/600 reads (59%) | called by pindel, varscan2
- ZNF354A | c.424T>G p.F142V | Missense Mutation (SNP) | VAF 340/685 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF608 | c.4460C>T p.S1487F | Missense Mutation (SNP) | VAF 147/492 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF682 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 342/343 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF862 | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 208/696 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFAP1 | c.1149G>A p.L383= | Silent (SNP) | VAF 156/318 reads (49%) | called by muse, mutect2, varscan2
- C15orf39 | c.1290G>A p.V430= | Silent (SNP) | VAF 513/768 reads (67%) | called by muse, mutect2, varscan2
- DIS3L | c.2484C>T p.F828= (on ENST00000319212 / NM_001143688.3; = p.F745= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 224/360 reads (62%) | called by muse, mutect2, varscan2
- EML4 | c.2103C>T p.L701= | Silent (SNP) | VAF 130/293 reads (44%) | called by muse, mutect2, varscan2
- ENO1 | c.594G>A p.E198= | Silent (SNP) | VAF 169/364 reads (46%) | called by muse, mutect2, varscan2
- FAM83D | c.1131C>T p.H377= | Silent (SNP) | VAF 201/863 reads (23%) | called by muse, mutect2, varscan2
- FAM83G | c.1819C>A p.R607= | Silent (SNP) | VAF 35/689 reads (5%) | called by muse, mutect2
- FH | c.1080A>G p.E360= | Silent (SNP) | VAF 32/759 reads (4%) | called by muse, mutect2
- GPR4 | c.915C>T p.L305= | Silent (SNP) | VAF 299/1155 reads (26%) | catalogued as rs376828367; called by muse, mutect2, varscan2
- MGAM2 | c.3822A>T p.P1274= | Silent (SNP) | VAF 104/337 reads (31%) | called by muse, mutect2, varscan2
- MTNR1B | c.528C>T p.F176= | Silent (SNP) | VAF 544/546 reads (100%) | catalogued as COSV57068279; called by muse, mutect2, varscan2
- NLRP8 | c.2844G>A p.L948= | Silent (SNP) | VAF 129/535 reads (24%) | called by muse, mutect2, varscan2
- PCIF1 | c.1149C>G p.L383= | Silent (SNP) | VAF 265/533 reads (50%) | called by muse, mutect2, varscan2
- PCOLCE2 | c.15C>T p.N5= | Silent (SNP) | VAF 188/537 reads (35%) | catalogued as rs887763011; called by muse, mutect2, varscan2
- SCOC | c.156C>T p.L52= | Silent (SNP) | VAF 361/362 reads (100%) | catalogued as rs1040903851; called by muse, mutect2, varscan2
- SOX1 | c.867C>T p.G289= | Silent (SNP) | VAF 48/83 reads (58%) | called by muse, varscan2
- STARD9 | c.12117G>A p.P4039= | Silent (SNP) | VAF 479/720 reads (67%) | catalogued as rs922143606; called by muse, mutect2, varscan2
- STK40 | c.705G>A p.G235= | Silent (SNP) | VAF 132/325 reads (41%) | called by muse, mutect2, varscan2
- TBC1D31 | c.1185G>C p.L395= | Silent (SNP) | VAF 235/468 reads (50%) | called by muse, mutect2, varscan2
- ZNF14 | c.30C>T p.A10= | Silent (SNP) | VAF 262/262 reads (100%) | catalogued as rs200630211, COSV59849718; called by muse, varscan2
- ZNF888 | c.51C>T p.F17= | Silent (SNP) | VAF 155/1066 reads (15%) | catalogued as COSV101480810; called by muse, mutect2
- CHST15 | c.*2173C>A | 3'UTR (SNP) | VAF 13/469 reads (3%) | called by muse, mutect2
- STAT5B | c.*297G>T | 3'UTR (SNP) | VAF 418/418 reads (100%) | called by muse, varscan2
